Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZR, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZR-01A (Primary Tumor).

Surgical Pathology Report

DOB:
Physician:

Collected:

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) LEFT THYROID LOBE AND ISTHMUS:

PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT

Location: Left lobe

Multi-focal: No

Size = 2.2 cm

Extrathyroidal extension: Absent

Lymphovascular invasion: Present

Resection Margins: Negative

Lymph nodes: No lymph nodes present

ICD-O-3

Path: Carcinoma, papillary, follicular variant

8340/3

CQCF: carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS C73.9

fw
6/17/12

GROSS DESCRIPTION

(A) LEFT THYROID LOBE AND ISTHMUS - A hemithyroidectomy specimen (4.0 x 1.5 x 1.5 cm) contains a well-circumscribed pink-tan nodule within the superior aspect of the left lobe (2.2 x 1.5 x 1.5 cm). The nodule appears confined to the thyroid with a smooth overlying thyroid surface. The isthmus is unremarkable. The specimen is serially sectioned and submitted from superior to inferior in A1-A6 with A7 isthmus.

CLINICAL HISTORY

Follicular neoplasm, left thyroid.

CONSULTANT(S)

SNOMED CODES

T-B6000, M-83403,

"Some tests reported here may have been developed and performance characteristics determined by These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Source: NCI Genomic Data Commons file 843b0444-4473-4529-8f43-9fdb8d4aedeb (TCGA-EL-A3ZR.AC8F850D-6F04-42C9-AA22-2532944E8C6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).